Gene-level copy-number profile of tumor specimen TCGA-CD-A48C-01A from TCGA case TCGA-CD-A48C, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 80.0 years (29,203 days).
Specimen TCGA-CD-A48C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.75ecd185-0f83-47da-9652-49d57208468a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CD-A48C-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bcf8cf10-72fc-4601-9cdd-324d9f57f46b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 878; copy number 2: 2,101; copy number 3: 15,865; copy number 4: 23,545; copy number 5: 6,579; copy number 6: 3,564; copy number 7: 2,017; copy number 8: 3,129; copy number 9: 219; copy number 10: 310; copy number 11: 278; copy number 12: 28; copy number 13: 341; copy number 14: 42; copy number 15: 446; copy number 16: 1; copy number 17: 2; copy number 19: 28; copy number 20: 36; copy number 24: 18; copy number 26: 129; copy number 27: 28; copy number 29: 57; copy number 32: 3; copy number 33: 67; copy number 36: 34; copy number 40: 2; copy number 49: 12; copy number 54: 43; copy number 65: 4; copy number 82: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CD-A48C-01A-11D-A24C-01): tumor purity 0.58, ploidy 4.3, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,020 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 9–11 (broad region; genes not listed).
- chr7:69,125,270–92,836,573, 352 genes, copy number 12–13 (within-gene range 8–13) (broad region; genes not listed).
- chr8:10,054,292–21,298,168, 236 genes, copy number 9–26 (within-gene range 3–26) (broad region; genes not listed).
- chr9:24,542,952–24,545,946, 1 gene, copy number 10: IZUMO3.
- chr11:66,435,075–79,612,300, 446 genes, copy number 15 (within-gene range 8–15) (broad region; genes not listed).
- chr11:134,274,245–135,075,908, 16 genes, copy number 12 (within-gene range 7–12): GLB1L3, AP000859.1, GLB1L2, B3GAT1, B3GAT1-DT, AP004550.1, AP001999.3, AP001999.1, AP001999.2, LINC02706, LINC02714, AP003062.2, LINC02697, AP003062.1, LINC02717, LINC02684.
- chr12:2,269,776–3,593,973, 38 genes, copy number 16–20 (within-gene range 4–27): CACNA1C-IT3, AC005293.1, AC005414.1, CACNA1C-AS3, AC007618.1, CACNA1C-AS2, CACNA1C-AS1, ITFG2-AS1, AC092471.2, LINC02371, IQSEC3P1, AC092471.1, RPL23AP14, CBX3P4, FKBP4, ITFG2-AS1, AC005841.1, ITFG2, NRIP2, TEX52, FOXM1, RHNO1, TULP3, AC005911.1, RNU6-1315P, TEAD4, AC125807.2, AC125807.1, TSPAN9, Metazoa_SRP, TSPAN9-IT1, AC005912.2, AC005912.1, AC005865.1, AC005865.2, LINC02827, LINC02417, PRMT8.
- chr12:3,606,633–3,764,819, 4 genes, copy number 27: CRACR2A, AC005831.1, RNU6-174P, AC006207.1.
- chr12:8,602,170–10,223,128, 78 genes, copy number 19–33 (within-gene range 4–33) (broad region; genes not listed).
- chr12:22,395,088–24,562,544, 18 genes, copy number 27–54 (within-gene range 5–54): AC087318.1, AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1, AC087235.2, AC087235.1, SOX5, AC087260.1, MIR920, SOX5-AS1.
- chr12:24,642,687–27,014,434, 53 genes, copy number 12–54: AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1, AC023051.2, INTS13, FGFR1OP2, TM7SF3, AC024896.1.
- chr12:56,822,985–57,818,704, 65 genes, copy number 14–29 (within-gene range 4–29) (broad region; genes not listed).
- chr12:75,480,753–75,511,636, 3 genes, copy number 32 (within-gene range 4–32): GLIPR1, AC121761.1, KRR1.

Autosomal genes at a single copy (total copy number 1): 878. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
